Gene-level copy-number profile of tumor specimen ALCH-AFJZ-TTP1-A from ALCHEMIST case ALCH-AFJZ, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Squamous cell carcinoma, NOS; Age at diagnosis: 74.2 years (27,102 days).
Specimen ALCH-AFJZ-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 0297c1de-278a-474d-b595-63961a565e76.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-AFJZ-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,801 have no estimate.
https://portal.gdc.cancer.gov/files/9041229d-ea3e-49f6-b453-1b5f49d7bd8f

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 349; copy number 1: 2,205; copy number 2: 23,151; copy number 3: 15,047; copy number 4: 15,246; copy number 5: 716; copy number 6: 931; copy number 7: 323; copy number 8: 455; copy number 9: 176; copy number 10: 202; copy number 12: 12; copy number 16: 4; copy number 44: 5.

Homozygous deletions (total copy number 0; autosomes only): 149 genes in 12 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:2,425,980–2,505,532, 3 genes: PLCH2, AL139246.1, AL139246.4.
- chr8:22,114,419–22,141,951, 2 genes: HR, REEP4.
- chr8:39,451,045–39,522,852, 1 gene: ADAM3A.
- chr10:132,186,948–132,205,759, 1 gene: DPYSL4.
- chr11:61,873,519–61,920,269, 3 genes: FADS3, MIR6746, RAB3IL1.
- chr13:113,008,778–113,010,319, 2 genes (within-gene range 0–2): AL356740.2, AL356740.3.
- chr14:105,620,506–105,626,066, 2 genes: IGHG4, MIR8071-1.
- chr14:105,672,308–106,481,706, 126 genes (within-gene range 0–1) (broad region; genes not listed).
- chr14:106,531,141–106,538,344, 2 genes (within-gene range 0–1): IGHVIII-47-1, IGHV3-48.
- chr17:3,088,484–3,127,581, 3 genes: OR1D2, OR1E3, OR1G1.
- chr19:1,874,871–1,885,496, 3 genes: AC012615.1, AC012615.5, ABHD17A.
- chr21:44,158,740–44,160,076, 1 gene: LINC01678.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 2,818 genes in 31 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:11,869–157,887, 15 genes, copy number 5–44: DDX11L1, WASH7P, MIR6859-1, MIR1302-2HG, MIR1302-2, OR4G4P, OR4G11P, OR4F5, AL627309.1, AL627309.3, CICP27, AL627309.6, AL627309.7, AL627309.2, RNU6-1100P.
- chr2:27,325,849–27,988,087, 26 genes, copy number 6 (within-gene range 4–6): GTF3C2, GTF3C2-AS1, AC074117.1, EIF2B4, SNX17, ZNF513, PPM1G, FTH1P3, NRBP1, KRTCAP3, IFT172, AC074117.2, RNU6-986P, FNDC4, GCKR, C2orf16, ZNF512, AC074091.2, CCDC121, GPN1, AC074091.1, SUPT7L, SLC4A1AP, LINC01460, MRPL33, RBKS.
- chr2:27,896,116–27,897,195, 1 gene, copy number 6 (within-gene range 4–6): MYG1P1.
- chr2:38,981,549–39,124,345, 1 gene, copy number 7 (within-gene range 4–7): SOS1.
- chr2:39,082,589–51,225,575, 179 genes, copy number 5–7 (within-gene range 4–7) (broad region; genes not listed).
- chr2:52,570,648–55,952,014, 54 genes, copy number 5: CRTC1P1, FTH1P6, MIR4431, AC010967.1, AC010967.2, AC010967.3, AC069157.2, AC069157.1, ASB3, RNU6-997P, CHAC2, ERLEC1, MIR3682, GPR75, PSME4, ACYP2, RPL21P30, HMGB1P31, AC008280.1, AC008280.2, RNU7-172P, TSPYL6, C2orf73, SPTBN1, SPTBN1-AS1, RPL23AP32, AC092839.1, AC093110.1, EML6, EML6-AS1, AC104781.1, RNU7-81P, RTN4, RNU6-433P, CLHC1, AC012358.1, CDPF1P1, RPS27A, MTIF2, PRORSD1P, AC012358.2, Y_RNA, CCDC88A, BTF3P5, RNU6-775P, RNU6-221P, RNU6-634P, CFAP36, PPP4R3B, AC015982.1, AC015982.2, PNPT1, EFEMP1, RN7SKP208.
- chr2:59,014,354–71,984,434, 270 genes, copy number 5–16 (within-gene range 4–16) (broad region; genes not listed).
- chr3:139,353,946–198,123,232, 1,003 genes, copy number 6–10 (within-gene range 3–10) (broad region; genes not listed).
- chr4:68,509,441–68,568,527, 2 genes, copy number 9 (within-gene range 3–9): UGT2B29P, UGT2B17.
- chr6:19,323,428–19,839,080, 1 gene, copy number 7 (within-gene range 3–7): LNC-LBCS.
- chr6:19,612,755–23,404,132, 35 genes, copy number 7: KRT18P38, UQCRFS1P3, RNU6-801P, ID4, AL008627.1, MBOAT1, AL158198.1, AL158198.2, E2F3, RN7SL128P, E2F3-IT1, RNU6-141P, Y_RNA, CDKAL1, AL035090.1, AL513188.1, RNU6-150P, AL031767.1, LINC00581, AL512380.1, AL512380.2, SOX4, BOLA2P3, CASC15, AL136313.1, RN7SKP240, NBAT1, AL359694.1, PRL, HDGFL1, AL033539.1, AL035401.1, AL591416.1, RNU6-1060P, AL139231.1.
- chr6:25,061,626–25,452,263, 1 gene, copy number 6 (within-gene range 4–6): CMAHP.
- chr6:25,181,359–28,732,904, 186 genes, copy number 6 (broad region; genes not listed).
- chr6:35,342,558–38,715,217, 86 genes, copy number 5 (broad region; genes not listed).
- chr6:41,026,895–60,546,660, 343 genes, copy number 5–8 (broad region; genes not listed).
- chr6:71,075,564–79,081,371, 105 genes, copy number 5–10 (broad region; genes not listed).
- chr7:88,759,700–89,496,918, 3 genes, copy number 5 (within-gene range 3–5): ZNF804B, TEX47, AC002383.1.
- chr8:55,773,446–56,014,169, 5 genes, copy number 7: TGS1, LYN, AC018607.1, SNORA1B, RN7SL798P.
- chr9:35,673,918–35,758,585, 10 genes, copy number 6 (within-gene range 3–6): CA9, TPM2, TLN1, MIR6852, CREB3, MIR6853, GBA2, RGP1, MSMP, AL133410.2.
- chr9:35,791,591–35,828,732, 4 genes, copy number 6 (within-gene range 4–6): NPR2, SPAG8, HINT2, AL133410.3.
- chr9:35,909,490–43,045,120, 193 genes, copy number 5–8 (within-gene range 4–8) (broad region; genes not listed).
- chr10:42,279,734–42,281,819, 1 gene, copy number 6: PABPC1P8.
- chr15:24,101,827–24,823,365, 1 gene, copy number 5 (within-gene range 3–5): PWRN1.
- chr15:24,558,060–26,134,001, 114 genes, copy number 5 (broad region; genes not listed).
- chr15:40,075,204–40,108,892, 4 genes, copy number 6: AC021755.2, AC021755.3, BMF, BMF-AS1.
- chr18:54,268,346–54,407,114, 5 genes, copy number 5: AC093462.1, POLI, STARD6, C18orf54, SNRPGP2.
- chr18:77,622,552–78,140,887, 7 genes, copy number 5–8: AC123786.1, AC123786.2, RNA5SP461, LINC01029, AC134978.1, RNU6-655P, AC107892.1.
- chr18:78,795,612–78,928,494, 4 genes, copy number 7: AC044873.1, AC091027.2, AC091027.1, AC091027.3.
- chr18:79,638,928–80,247,514, 20 genes, copy number 5: AC068473.1, AC068473.5, CTDP1, AC068473.2, AC021594.1, AC021594.2, KCNG2, AC114341.1, SLC66A2, HSBP1L1, TXNL4A, AC090360.1, RBFA, RBFADN, SLC25A6P4, ADNP2, PARD6G-AS1, PARD6G, AC139100.2, AC139100.1.
- chr19:39,433,137–39,476,670, 2 genes, copy number 6: RPS16, SUPT5H.
- chr22:16,572,027–19,291,719, 137 genes, copy number 5 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 2,033. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
